Somatic mutation profile of tumor specimen TCGA-25-2392-01A (aliquot TCGA-25-2392-01A-01W-0799-08) from TCGA case TCGA-25-2392, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 75.7 years (27,667 days).
Specimen TCGA-25-2392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b5fba69-959b-4264-99bc-e74ba2a10ab6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2392-10A (Blood Derived Normal), aliquot TCGA-25-2392-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aa3e702-435f-42c0-b3b4-5639e4b63858

The open-access MAF lists 131 somatic variants for this specimen: 97 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 30, Frame Shift Del 4, Nonsense Mutation 3, Intron 3, Splice Site 3, 3'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 37/58 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.881G>C p.R294P | Missense Mutation (SNP) | VAF 103/499 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.855); catalogued as COSV100741592, COSV62789109; called by muse, mutect2, varscan2
- ABCC8 | c.4060G>T p.D1354Y | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV56847033, COSV56850299; called by muse, mutect2, varscan2
- ACIN1 | c.2255A>C p.Q752P | Missense Mutation (SNP) | VAF 47/428 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV52973850; called by muse, mutect2, varscan2
- ADAMTS17 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 42/415 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51474370; called by muse, mutect2
- ADD2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 126/769 reads (16%) | catalogued as COSV52455835; called by muse, mutect2, varscan2
- ANK3 | c.11254T>A p.C3752S | Missense Mutation (SNP) | VAF 118/480 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV55047008; called by muse, mutect2, varscan2
- C1orf50 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65308120; called by muse, mutect2, varscan2
- CACNA1A | c.1671G>C p.G557= | Splice Region (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100801434; called by muse, mutect2, varscan2
- CDK12 | c.2645G>T p.R882L | Missense Mutation (SNP) | VAF 125/462 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70999516, COSV71000400; called by muse, mutect2, varscan2
- CELF4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs372830155; called by muse, mutect2, varscan2
- COPB1 | c.2573A>T p.N858I | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV99999328; called by muse, mutect2
- CRNKL1 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV99843681; called by muse, mutect2, varscan2
- CSRNP1 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs142952358, COSV56187375; called by muse, mutect2
- CTNNBL1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 110/350 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as rs763515386, COSV63743910; called by muse, mutect2, varscan2
- CXCL9 | c.312A>T p.K104N | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.071); catalogued as COSV53578362; called by muse, mutect2, varscan2
- DCLK2 | c.1328T>A p.I443K | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99651546; called by muse, mutect2
- DIS3L | c.2857-1G>C p.X953_splice (on ENST00000319212 / NM_001143688.3; = p.X870_splice on NM_133375.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV56019422; called by muse, varscan2
- DLG2 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 1055/1229 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54625985; called by muse, mutect2, varscan2
- DNAJB11 | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54001988; called by muse, mutect2, varscan2
- DPY19L3 | c.1681C>G p.L561V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60474969; called by muse, mutect2, varscan2
- DSCAML1 | c.3731T>C p.I1244T (on ENST00000321322; = p.I1184T on NM_020693.4) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.209); catalogued as COSV58383335; called by muse, mutect2, varscan2
- EMILIN1 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV53153598; called by muse, mutect2
- ENTHD1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV57317686; called by muse, mutect2, varscan2
- ESYT2 | c.1828C>T p.Q610* (on ENST00000613624; = p.Q534* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99276296; called by muse, mutect2, varscan2
- EYA1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 195/2364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100378759; called by muse, mutect2
- EZH1 | c.965A>G p.K322R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV70548798; called by muse, mutect2, varscan2
- FABP9 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 28/714 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as COSV100986923; called by muse, mutect2
- FBXL18 | c.1744G>C p.D582H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV66107459; called by muse, mutect2, varscan2
- FGFR4 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172824038, COSV52801476; called by muse, mutect2, varscan2
- FSTL5 | c.914C>A p.S305Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60183495; called by muse, mutect2, varscan2
- GALNT1 | c.140-1G>C p.X47_splice | Splice Site (SNP) | VAF 25/157 reads (16%) | catalogued as COSV52451140; called by muse, mutect2, varscan2
- GPR88 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV100159446; called by muse, mutect2, varscan2
- GZMH | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 70/607 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as COSV53537748; called by muse, mutect2, varscan2
- H2AC17 | c.21G>C p.Q7H | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV58152086; called by muse, mutect2, varscan2
- HEXIM1 | c.49A>T p.N17Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV60176727; called by muse, mutect2, varscan2
- HMCN1 | c.16746G>C p.L5582F | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54909722; called by muse, mutect2
- IL36A | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs780234919, COSV52082710, COSV52083701; called by muse, mutect2, varscan2
- IQCD | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV55320539, COSV55323313; called by muse, mutect2
- IQCN | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV66572762; called by muse, mutect2, varscan2
- IRAG2 | c.3899G>A p.R1300K (on ENST00000636465; = p.R345K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as COSV57230396; called by muse, mutect2, varscan2
- IRF2BPL | c.2334del p.E779Kfs*6 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as COSV53147186; called by mutect2, pindel, varscan2
- KCNJ10 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 255/1091 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs200320916, COSV100927880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNU1 | c.1278T>A p.D426E | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101299003; called by muse, mutect2
- KLF3 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.177); catalogued as COSV54709745; called by muse, mutect2, varscan2
- KLHL32 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.621); catalogued as COSV65110694; called by muse, varscan2
- LARP7 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.165); catalogued as COSV60520326; called by muse, mutect2, varscan2
- LCOR | c.448A>T p.K150* | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | catalogued as COSV63630287; called by muse, mutect2, varscan2
- LIMCH1 | c.3196A>C p.N1066H | Missense Mutation (SNP) | VAF 101/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58275631; called by muse, mutect2, varscan2
- LRP12 | c.1340del p.N447Tfs*41 | Frame Shift Del (DEL) | VAF 62/446 reads (14%) | catalogued as rs1217102319, COSV52630472; called by mutect2, pindel, varscan2
- LRP2 | c.5875C>A p.Q1959K | Missense Mutation (SNP) | VAF 60/434 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55543473, COSV99787148; called by muse, mutect2, varscan2
- MAST2 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 146/587 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV63616380; called by muse, mutect2, varscan2
- MDN1 | c.13376T>C p.L4459P | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs371257592; called by muse, mutect2, varscan2
- MMP9 | c.1105G>T p.G369W | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812361; called by muse, mutect2
- NFATC2IP | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV57909805; called by muse, mutect2, varscan2
- NOC3L | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149958947; called by muse, mutect2, varscan2
- NXPE4 | c.934A>T p.T312S (on ENST00000375478 / NM_001077639.2; = p.T28S on NM_017678.3) | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV64943477; called by muse, mutect2, varscan2
- OR10A7 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58277849; called by muse, mutect2, varscan2
- OR2F2 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 126/335 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs202173407; called by muse, mutect2, varscan2
- OTULIN | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52505049; called by muse, mutect2, varscan2
- PDLIM1 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV61473570; called by muse, mutect2, varscan2
- PLEKHA6 | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55329580, COSV55330708; called by muse, mutect2, varscan2
- PLK4 | c.1359-1G>A p.X453_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99584470; called by muse, mutect2
- PLXNA2 | c.3265G>T p.V1089F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100885209; called by muse, mutect2
- PRKAG3 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs747360681, COSV52100984; called by muse, mutect2, varscan2
- PROX1 | c.1565C>G p.T522R | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV54776444, COSV54776998; called by muse, mutect2, varscan2
- PTGFR | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs145816454, COSV66114518; called by muse, mutect2, varscan2
- QSOX2 | c.1622A>G p.E541G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV62393515; called by muse, mutect2, varscan2
- RALGPS1 | c.733G>C p.V245L | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs530706814, COSV99401056; called by muse, mutect2, varscan2
- RASAL1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 216/710 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV55654174; called by muse, varscan2
- RELN | c.3826G>A p.A1276T | Missense Mutation (SNP) | VAF 110/479 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58988600; called by muse, mutect2, varscan2
- RFX6 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV60583738; called by mutect2, varscan2
- RPAP3 | c.361T>G p.S121A | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1279256902, COSV50041386; called by muse, mutect2
- SDS | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.055); catalogued as COSV99785216; called by muse, mutect2
- SH2B1 | c.1046A>C p.E349A | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV59461057; called by muse, mutect2, varscan2
- SPCS3 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV72419002; called by muse, mutect2, varscan2
- SPRTN | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV99149514; called by muse, mutect2
- SRC | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV100657987; called by muse, mutect2, varscan2
- STRADA | c.691C>G p.H231D (on ENST00000336174 / NM_001363786.1; = p.H194D on NM_153335.6) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768390501, COSV55561697, COSV55564232; called by muse, mutect2, varscan2
- SYNC | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.259); catalogued as COSV65130017; called by muse, mutect2, varscan2
- TANC1 | c.4691G>C p.S1564T | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV55084055; called by muse, mutect2, varscan2
- TEP1 | c.5431G>C p.E1811Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV52988947; called by muse, mutect2, varscan2
- TFCP2 | c.204A>T p.Q68H | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV56931620; called by muse, mutect2, varscan2
- TRIB3 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53930550; called by muse, mutect2, varscan2
- TRIO | c.5013C>G p.N1671K | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV60078619; called by muse, varscan2
- TTN | c.45578T>G p.V15193G (on ENST00000591111; = p.V7769G on NM_003319.4) | Missense Mutation (SNP) | VAF 171/614 reads (28%) | PolyPhen benign (0); catalogued as COSV59914316; called by muse, mutect2, varscan2
- TUT4 | c.1232G>T p.S411I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99931927; called by muse, mutect2
- UNC80 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547993640, COSV55884699; called by muse, mutect2, varscan2
- USH2A | c.11261G>C p.G3754A | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as COSV56334807; called by muse, mutect2, varscan2
- ZBTB18 | c.1168A>T p.S390C | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62396393; called by muse, mutect2, varscan2
- ZMYND12 | c.145A>C p.I49L | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV65341718; called by muse, mutect2, varscan2
- ZNF208 | c.1839A>C p.E613D | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV68101636; called by muse, mutect2, varscan2
- ZNF671 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58051885; called by muse, mutect2, varscan2
- NCKAP1 | c.281_284del p.Y94Sfs*4 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- OR4F5 | c.321_346del p.L108Yfs*50 | Frame Shift Del (DEL) | VAF 73/407 reads (18%) | called by mutect2, pindel
- USP44 | c.1982_1999del p.T661_C666del | In Frame Del (DEL) | VAF 78/208 reads (38%) | called by mutect2, pindel, varscan2
- ZDHHC7 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2
- ADGRA2 | c.1152C>T p.P384= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV59441325; called by muse, mutect2, varscan2
- ATP6V1A | c.1482G>A p.Q494= | Silent (SNP) | VAF 57/204 reads (28%) | catalogued as COSV56361237; called by muse, mutect2, varscan2
- BLOC1S4 | c.357G>C p.P119= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV57900843; called by muse, mutect2
- CATSPERD | c.597C>T p.G199= | Silent (SNP) | VAF 35/502 reads (7%) | catalogued as rs748950630, COSV101062427; called by muse, mutect2
- CCT4 | c.516C>T p.N172= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1440409600, COSV101075088; called by muse, mutect2, varscan2
- CIDEA | c.606G>A p.K202= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100254962; called by muse, mutect2, varscan2
- CMYA5 | c.4785A>T p.A1595= | Silent (SNP) | VAF 308/539 reads (57%) | catalogued as COSV71404307; called by muse, mutect2, varscan2
- CPA1 | c.630C>T p.L210= | Silent (SNP) | VAF 30/320 reads (9%) | catalogued as rs377138792; ClinVar: likely benign; called by muse, mutect2
- ERLEC1 | c.906G>A p.E302= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV51750740; called by muse, mutect2, varscan2
- EXOC5 | c.433T>C p.L145= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1201191453, COSV61770243; called by muse, mutect2, varscan2
- FAM91A1 | c.1557T>A p.P519= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as COSV100593469; called by muse, varscan2
- FBXW8 | c.1098G>T p.S366= (on ENST00000309909; = p.S404= on NM_012174.1) | Silent (SNP) | VAF 166/224 reads (74%) | catalogued as rs773431344, COSV59297020, COSV59298166; called by muse, mutect2, varscan2
- FOXJ3 | c.606G>A p.L202= | Silent (SNP) | VAF 21/220 reads (10%) | catalogued as COSV62360259; called by muse, mutect2
- GPRIN1 | c.246C>A p.S82= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV56135334; called by muse, mutect2, varscan2
- GPRIN2 | c.288C>T p.G96= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100966313, COSV100966515; called by muse, varscan2
- GRK5 | c.195G>C p.L65= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100962880; called by muse, mutect2
- JAK1 | c.1434C>T p.T478= | Silent (SNP) | VAF 70/216 reads (32%) | catalogued as rs55788790, COSV61087960; called by muse, mutect2, varscan2
- LIMK2 | c.730C>T p.L244= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as COSV59181551; called by muse, mutect2, varscan2
- LRRC18 | c.336G>A p.G112= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV53282327; called by muse, mutect2, varscan2
- MAGEA3 | c.777G>T p.R259= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV64755859; called by muse, mutect2, varscan2
- OSBPL1A | c.2616C>T p.C872= (on ENST00000319481 / NM_080597.4; = p.C359= on NM_018030.4) | Silent (SNP) | VAF 77/463 reads (17%) | catalogued as rs555122944, COSV60195801; called by muse, mutect2, varscan2
- OTOP3 | c.297T>A p.T99= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as COSV100172649; called by muse, mutect2
- PLA2G12B | c.312C>T p.G104= | Silent (SNP) | VAF 71/696 reads (10%) | catalogued as rs1460607517, COSV65978289; called by muse, mutect2
- RPS6KA3 | c.1011A>G p.R337= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV65387055; called by muse, mutect2, varscan2
- SETD5 | c.3981T>C p.S1327= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV56708127; called by muse, mutect2, varscan2
- SMTNL2 | c.1380C>T p.F460= (on ENST00000389313 / NM_001114974.2; = p.F316= on NM_198501.3) | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs747868778, COSV100130604; called by muse, mutect2
- TRPM3 | c.4734C>T p.D1578= (on ENST00000357533 / NM_001366142.2; = p.D1433= on NM_020952.6) | Silent (SNP) | VAF 26/438 reads (6%) | catalogued as COSV100676840; called by muse, mutect2
- TRPM3 | c.3309G>T p.V1103= (on ENST00000357533 / NM_001366142.2; = p.V958= on NM_020952.6) | Silent (SNP) | VAF 32/328 reads (10%) | catalogued as rs376251043; called by muse, mutect2
- TSPAN14 | c.363C>T p.D121= | Silent (SNP) | VAF 76/480 reads (16%) | catalogued as COSV59367244; called by muse, mutect2, varscan2
- UVRAG | c.963A>G p.L321= | Silent (SNP) | VAF 24/464 reads (5%) | catalogued as COSV100638227; called by muse, mutect2
- CCDC141 | c.4325+23C>T | Intron (SNP) | VAF 23/195 reads (12%) | catalogued as COSV55369832; called by muse, mutect2, varscan2
- FAT4 | c.5176-4793C>G | Intron (SNP) | VAF 29/208 reads (14%) | catalogued as COSV100627504; called by muse, mutect2, varscan2
- MFSD4B | c.*743G>C | 3'UTR (SNP) | VAF 12/201 reads (6%) | catalogued as COSV100920550; called by muse, mutect2
- SUN1 | c.659-1437T>G | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100568572; called by muse, mutect2, varscan2
